FM case AD13148 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/f40023a4-8758-4dd4-b83d-e68f9042a9ea

Female, 60.6 years: Mucinous carcinoma (ICD-O-3 8480/3) of the appendix; primary biopsied or resected from the appendix. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
